Somatic mutation profile of tumor specimen TCGA-04-1371-01A (aliquot TCGA-04-1371-01A-01W-0492-08) from TCGA case TCGA-04-1371, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.2 years (21,243 days).
Specimen TCGA-04-1371-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b796d5e9-0003-4d73-91f4-55ce5cda8194.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1371-11A (Solid Tissue Normal), aliquot TCGA-04-1371-11A-01W-0492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1c5c9a4-0515-48e9-8739-e339f7b12398

The open-access MAF lists 33 somatic variants for this specimen: 21 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 10, Frame Shift Ins 3, Nonsense Mutation 1, Intron 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL3 | c.1895C>G p.S632C (on ENST00000506720 / NM_001322402.2; = p.S564C on NM_015236.6) | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100800325; called by muse, mutect2, varscan2
- C5AR2 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as rs759726681, COSV57256195; called by muse, mutect2, varscan2
- FBN2 | c.5467G>T p.V1823L | Missense Mutation (SNP) | VAF 71/190 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.287); catalogued as COSV52493323; called by muse, mutect2, varscan2
- FLT3 | c.2957C>T p.P986L | Missense Mutation (SNP) | VAF 44/348 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as rs587778369, COSV54047766, COSV54049596; ClinVar: not provided; called by muse, mutect2, varscan2
- HSPG2 | c.5373C>A p.F1791L | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.991); catalogued as COSV65970617; called by muse, varscan2
- RBM15B | c.1738dup p.A580Gfs*23 | Frame Shift Ins (INS) | VAF 4/17 reads (24%) | catalogued as rs782096261; called by mutect2, pindel, varscan2
- ZMIZ1 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.142); catalogued as rs756182598, COSV57895248; called by muse, mutect2, varscan2
- APH1A | c.595C>A p.L199M | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.315); called by muse, mutect2
- API5 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- BMP15 | c.1052G>A p.S351N | Missense Mutation (SNP) | VAF 9/291 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.041); called by muse, mutect2
- KRI1 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- NDRG1 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 14/92 reads (15%) | called by muse, mutect2, varscan2
- NFKBIZ | c.1636G>C p.E546Q | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RYR3 | c.7381C>A p.Q2461K (on ENST00000389232; = p.Q2462K on NM_001036.6) | Missense Mutation (SNP) | VAF 81/422 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SAA1 | c.20T>G p.L7R | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- SPAG17 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 24/432 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- STOML1 | c.298dup p.Q100Pfs*13 | Frame Shift Ins (INS) | VAF 6/38 reads (16%) | called by mutect2, pindel, varscan2
- TAFA2 | c.136G>T p.V46L | Missense Mutation (SNP) | VAF 85/517 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TOP2A | c.626dup p.N210Qfs*13 | Frame Shift Ins (INS) | VAF 338/953 reads (35%) | called by pindel, varscan2
- TOP2A | c.612_614del p.M204_E205delinsI | In Frame Del (DEL) | VAF 356/971 reads (37%) | called by pindel, varscan2
- ZP2 | c.577A>G p.R193G | Missense Mutation (SNP) | VAF 188/1053 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLDND2 | c.503G>A p.*168= | Silent (SNP) | VAF 25/80 reads (31%) | called by muse, mutect2, varscan2
- GNE | c.2241C>T p.Y747= (on ENST00000396594 / NM_001128227.3; = p.Y716= on NM_005476.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/508 reads (6%) | catalogued as rs757267858; called by muse, mutect2
- MLST8 | c.954G>A p.L318= | Silent (SNP) | VAF 46/48 reads (96%) | catalogued as rs368659999; called by muse, mutect2, varscan2
- PARP2 | c.1452G>T p.L484= | Silent (SNP) | VAF 18/361 reads (5%) | called by muse, mutect2
- USH2A | c.7893G>A p.E2631= | Silent (SNP) | VAF 50/179 reads (28%) | called by muse, mutect2, varscan2
- VRTN | c.2019G>A p.E673= | Silent (SNP) | VAF 8/111 reads (7%) | called by muse, mutect2
- VSTM4 | c.171G>A p.L57= | Silent (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- WDR4 | c.822C>T p.D274= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as rs772529334, COSV100375011; called by muse, mutect2
- WWC3 | c.705T>C p.N235= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs951857456, COSV66501663; called by muse, varscan2
- ZNF479 | c.1362C>T p.D454= | Silent (SNP) | VAF 18/608 reads (3%) | called by muse, mutect2
- LRP1 | c.841+3503C>T | Intron (SNP) | VAF 39/213 reads (18%) | catalogued as rs747699937; called by muse, mutect2, varscan2
- MIR892A | n.61C>T | RNA (SNP) | VAF 133/431 reads (31%) | called by muse, mutect2, varscan2
